Somatic mutation profile of tumor specimen MMRF_1560_1_BM_CD138pos (aliquot MMRF_1560_1_BM_CD138pos_T1_KBS5U_L03508) from MMRF case MMRF_1560, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.1 years (20,864 days).
Specimen MMRF_1560_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58157646-9a0f-403e-ae32-d830f3217df2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1560_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1560_1_PB_Whole_C2_KBS5U_L03512; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb3b549e-9625-42e5-bfd3-666f2d457fc8

The open-access MAF lists 68 somatic variants for this specimen: 25 protein-altering or splice-affecting, 7 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, 3'UTR 19, Intron 7, Silent 7, 5'UTR 5, Splice Region 4, 5'Flank 3, Nonsense Mutation 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 38/68 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913482, CM950469, COSV53390662; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CEP290 | c.1225A>C p.I409L | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780354351; called by muse, mutect2, varscan2
- CLEC12B | c.680+6T>A | Splice Region (SNP) | VAF 196/390 reads (50%) | catalogued as rs759327362; called by muse, mutect2, varscan2
- IGHV1-24 | c.113A>G p.K38R | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.246); catalogued as rs782748934; called by muse, mutect2, varscan2
- IGHV3-23 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.296); catalogued as rs782495642; called by muse, varscan2
- IGKJ1 | c.36C>G p.I12M | Missense Mutation (SNP) | VAF 118/139 reads (85%) | catalogued as rs3203340; called by muse, varscan2
- LTB | c.208+5G>A | Splice Region (SNP) | VAF 129/278 reads (46%) | catalogued as rs1366767390; called by muse, varscan2
- MAP3K5 | c.988A>G p.I330V | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs778590348; called by muse, mutect2, varscan2
- MINDY2 | c.1140A>C p.K380N | Missense Mutation (SNP) | VAF 61/110 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as rs1290001167; called by muse, mutect2, varscan2
- MYO18A | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 115/279 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.719); catalogued as COSV62866123; called by muse, mutect2, varscan2
- RNF43 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.267); catalogued as rs769498996; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC25A41 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 107/164 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.417); catalogued as rs1361576984; called by muse, mutect2, varscan2
- TMEM97 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 142/331 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1264655980, COSV56878667; called by muse, mutect2, varscan2
- ACACA | c.7039G>C p.A2347P | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- ATM | c.6926T>C p.L2309P | Missense Mutation (SNP) | VAF 75/165 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- B3GAT2 | c.885+3A>G | Splice Region (SNP) | VAF 161/374 reads (43%) | called by muse, mutect2, varscan2
- COQ2 | c.896C>G p.T299S | Missense Mutation (SNP) | VAF 84/170 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- IGHV2-70D | c.205C>G p.L69V | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- IPO7 | c.550C>A p.R184S | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT tolerated (0.14); PolyPhen benign (0.326); called by muse, varscan2
- MAML1 | c.2056G>T p.G686* | Nonsense Mutation (SNP) | VAF 10/156 reads (6%) | called by muse, mutect2
- OR13C4 | c.525T>A p.N175K | Missense Mutation (SNP) | VAF 108/235 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- OVCH1 | c.1177G>T p.V393F | Missense Mutation (SNP) | VAF 112/239 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- POLR2B | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- PTBP2 | c.730C>T p.L244= (on ENST00000426398 / NM_001300986.2; = p.L236= on NM_021190.4) | Splice Region (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- TMPO | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 136/303 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- CAPN2 | c.669C>T p.N223= | Silent (SNP) | VAF 35/75 reads (47%) | catalogued as rs1485717978; called by muse, mutect2, varscan2
- DHX30 | c.321C>T p.I107= (on ENST00000445061 / NM_138615.3; = p.I68= on NM_014966.3) | Silent (SNP) | VAF 49/126 reads (39%) | catalogued as rs375356846; called by muse, mutect2, varscan2
- MYO9B | c.3258G>A p.Q1086= | Silent (SNP) | VAF 46/112 reads (41%) | called by muse, mutect2
- SLC4A3 | c.3606C>T p.D1202= | Silent (SNP) | VAF 36/72 reads (50%) | catalogued as rs776819174; called by muse, mutect2, varscan2
- SP8 | c.1158C>T p.F386= (on ENST00000361443 / NM_198956.4; = p.F404= on NM_182700.6) | Silent (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- VWC2 | c.567G>A p.Q189= | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as rs371778744; called by muse, mutect2, varscan2
- ZFC3H1 | c.4152T>C p.D1384= | Silent (SNP) | VAF 40/84 reads (48%) | catalogued as COSV66430676; called by muse, mutect2, varscan2
- ANGPTL1 | c.*1120_*1127del | 3'UTR (DEL) | VAF 69/141 reads (49%) | called by mutect2, pindel, varscan2
- AP000769.5 | chr11:65499162 T>C | 5'Flank (SNP) | VAF 20/42 reads (48%) | catalogued as rs11540776; called by muse, varscan2
- AP000769.5 | chr11:65499224 T>G | 5'Flank (SNP) | VAF 26/68 reads (38%) | catalogued as rs186585894; called by muse, varscan2
- ARL15 | c.*1775G>A | 3'UTR (SNP) | VAF 41/95 reads (43%) | called by muse, mutect2, varscan2
- CAMKV | c.*605A>G | 3'UTR (SNP) | VAF 105/155 reads (68%) | called by muse, mutect2, varscan2
- CCDC146 | c.2277+113T>C | Intron (SNP) | VAF 24/57 reads (42%) | called by muse, varscan2
- CCDC88C | c.-111G>C | 5'UTR (SNP) | VAF 6/16 reads (38%) | called by muse, varscan2
- CDK6 | c.*8325C>T | 3'UTR (SNP) | VAF 47/130 reads (36%) | catalogued as rs1035361445; called by muse, mutect2, varscan2
- CLEC12B | c.*212G>A | 3'UTR (SNP) | VAF 28/70 reads (40%) | called by muse, varscan2
- DNAJC5G | chr2:27275192 G>T | 5'Flank (SNP) | VAF 81/193 reads (42%) | called by muse, mutect2, varscan2
- EIF5A2 | c.*1954A>C | 3'UTR (SNP) | VAF 181/276 reads (66%) | called by muse, mutect2, varscan2
- FBLN1 | c.80-1255C>A | Intron (SNP) | VAF 32/34 reads (94%) | called by muse, mutect2, varscan2
- HACD1 | c.*409G>T | 3'UTR (SNP) | VAF 22/46 reads (48%) | called by muse, varscan2
- HOXD10 | c.*235A>T | 3'UTR (SNP) | VAF 19/45 reads (42%) | catalogued as rs76652386, COSV50891482; called by muse, varscan2
- ING3 | c.267+889G>A | Intron (SNP) | VAF 56/107 reads (52%) | called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.*145T>G | 3'UTR (SNP) | VAF 28/98 reads (29%) | called by muse, mutect2, varscan2
- KCNAB1 | c.*524del | 3'UTR (DEL) | VAF 66/125 reads (53%) | called by mutect2, pindel, varscan2
- KDSR | c.*2074dup | 3'UTR (INS) | VAF 52/111 reads (47%) | called by mutect2, varscan2
- KIF1B | c.2115+10962G>A | Intron (SNP) | VAF 22/44 reads (50%) | called by muse, mutect2, varscan2
- LYRM7 | c.*387T>C | 3'UTR (SNP) | VAF 54/96 reads (56%) | called by muse, mutect2, varscan2
- MFAP3L | c.*1491del | 3'UTR (DEL) | VAF 26/56 reads (46%) | called by mutect2, varscan2
- MOGAT2 | c.*720G>A | 3'UTR (SNP) | VAF 60/109 reads (55%) | catalogued as rs376291660; called by muse, mutect2, varscan2
- NOS1 | c.*6554T>A | 3'UTR (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- PDLIM7 | c.-11-318G>C | Intron (SNP) | VAF 52/94 reads (55%) | called by muse, mutect2, varscan2
- PIK3CA | c.*2434G>C | 3'UTR (SNP) | VAF 112/327 reads (34%) | called by muse, mutect2, varscan2
- PPP1R3E | c.-142T>C | 5'UTR (SNP) | VAF 67/128 reads (52%) | called by muse, mutect2, varscan2
- PTGS1 | c.*56G>A | 3'UTR (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- PTPN2 | c.-43C>T | 5'UTR (SNP) | VAF 24/43 reads (56%) | catalogued as rs1344900769; called by muse, mutect2, varscan2
- PYROXD1 | c.-39C>T | 5'UTR (SNP) | VAF 35/68 reads (51%) | catalogued as rs373496176; called by muse, mutect2, varscan2
- SEPTIN7 | c.169+14259C>T | Intron (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- SKIDA1 | c.-773A>G | 5'UTR (SNP) | VAF 38/100 reads (38%) | called by muse, mutect2, varscan2
- SLITRK4 | chrX:143628050 T>G | 3'Flank (SNP) | VAF 23/25 reads (92%) | called by muse, mutect2, varscan2
- SORD2P | n.802C>G | RNA (SNP) | VAF 18/104 reads (17%) | called by muse, mutect2, varscan2
- SOX11 | c.*2053G>A | 3'UTR (SNP) | VAF 28/59 reads (47%) | catalogued as rs1220840100, COSV100431304, COSV58988063; called by muse, mutect2, varscan2
- TRIM61 | c.526-2246G>A | Intron (SNP) | VAF 44/91 reads (48%) | catalogued as COSV61417530; called by muse, mutect2, varscan2
- TXNIP | c.*1023G>C | 3'UTR (SNP) | VAF 82/170 reads (48%) | called by muse, mutect2, varscan2
